Somatic mutation profile of tumor specimen MP2PRT-PAUCMU-TMP1-A (aliquot MP2PRT-PAUCMU-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAUCMU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,707 days).
Specimen MP2PRT-PAUCMU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0c2ee4e-9d66-4efd-8186-ab83c291577f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCMU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCMU-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/378b7f8c-67fb-460e-b21a-744cbcacf2e8

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLEKHH1 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs748756908, COSV61287308; called by muse, mutect2, varscan2
- MYOCD | c.2399C>G p.A800G | Missense Mutation (SNP) | VAF 120/310 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC7A14 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 24/391 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.084); called by muse, mutect2
- TTN | c.3313G>T p.V1105F (on ENST00000591111; = p.V1059F on NM_003319.4) | Missense Mutation (SNP) | VAF 32/438 reads (7%) | PolyPhen benign (0.238); called by muse, mutect2
- PKD1L2 | n.2625C>G | RNA (SNP) | VAF 79/276 reads (29%) | catalogued as rs771781699; called by muse, mutect2, varscan2
